Somatic mutation profile of tumor specimen 0DIDST from CCDI case PBBVJB, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Rhabdomyoma, NOS; Tissue or organ of origin: Eyelid; Age at diagnosis: 6.8 years (2,480 days).
Specimen 0DIDST: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) eec4cd2e-3a51-4858-a779-7e8a5ccc6311.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DIDS2 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/efc70b49-3f10-458f-bde7-f41f45aab519

The open-access MAF lists 59 somatic variants for this specimen: 36 protein-altering or splice-affecting, 13 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, Silent 13, 5'UTR 4, Intron 4, 3'UTR 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CACNA1A | c.2356C>G p.R786G | Missense Mutation (SNP) | VAF 265/496 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.43); catalogued as COSV64204504; called by muse, varscan2
- CENPK | c.197G>A p.C66Y | Missense Mutation (SNP) | VAF 117/395 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.012); catalogued as COSV54467117; called by muse, varscan2
- DOP1B | c.4571C>T p.T1524M | Missense Mutation (SNP) | VAF 30/282 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as rs143442760; called by muse, varscan2
- FAM91A1 | c.2182G>A p.G728R | Missense Mutation (SNP) | VAF 166/1270 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58235728; called by muse, varscan2
- FLG | c.12098A>T p.N4033I | Missense Mutation (SNP) | VAF 122/241 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.075); catalogued as COSV64242576; called by muse, varscan2
- HERC5 | c.1648G>C p.V550L | Missense Mutation (SNP) | VAF 159/365 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.049); catalogued as rs367799604; called by muse, varscan2
- IGFBP1 | c.172G>A p.G58S | Missense Mutation (SNP) | VAF 109/540 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs753334604; called by muse, varscan2
- NF1 | c.4352A>G p.N1451S (on ENST00000358273 / NM_001042492.3; = p.N1430S on NM_000267.3) | Missense Mutation (SNP) | VAF 112/278 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs199474754, CM054013, COSV62206425; ClinVar: uncertain significance; called by muse, varscan2
- OSBPL10 | c.908C>T p.A303V | Missense Mutation (SNP) | VAF 156/352 reads (44%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as rs749055456, COSV101159864, COSV67340456; called by muse, varscan2
- OTOG | c.2068C>A p.L690M | Missense Mutation (SNP) | VAF 217/753 reads (29%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.991); catalogued as rs1442230509; called by muse, varscan2
- SMPDL3B | c.1087G>A p.E363K | Missense Mutation (SNP) | VAF 130/306 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as rs773456344; called by muse, varscan2
- SOGA3 | c.2233C>T p.R745C | Missense Mutation (SNP) | VAF 56/126 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV64107246; called by muse, varscan2
- SSH1 | c.2598C>G p.H866Q | Missense Mutation (SNP) | VAF 123/441 reads (28%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0); catalogued as rs142995244; called by muse, varscan2
- AGBL1 | c.1958G>T p.C653F | Missense Mutation (SNP) | VAF 170/400 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.085); called by muse, varscan2
- APOB | c.13544C>A p.A4515D | Missense Mutation (SNP) | VAF 181/612 reads (30%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.595); called by muse, varscan2
- C1R | c.2071G>A p.G691S (on ENST00000536053 / NM_001354346.2; = p.G677S on NM_001733.7) | Missense Mutation (SNP) | VAF 118/403 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- CMYA5 | c.2089G>T p.A697S | Missense Mutation (SNP) | VAF 166/590 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.162); called by muse, varscan2
- CNGA2 | c.760G>T p.A254S | Missense Mutation (SNP) | VAF 148/165 reads (90%) | SIFT tolerated (0.83); PolyPhen benign (0.018); called by muse, varscan2
- DCHS1 | c.8351T>C p.L2784P | Missense Mutation (SNP) | VAF 135/366 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, varscan2
- DTWD2 | c.736C>A p.R246S | Missense Mutation (SNP) | VAF 98/307 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.523); called by muse, varscan2
- ESRRA | c.86C>T p.T29I | Missense Mutation (SNP) | VAF 120/615 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.304); called by muse, varscan2
- FAM160A1 | c.2210A>G p.H737R | Missense Mutation (SNP) | VAF 136/498 reads (27%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, varscan2
- GYPE | c.223T>G p.Y75D | Missense Mutation (SNP) | VAF 155/360 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.554); called by muse, varscan2
- IGSF21 | c.213G>C p.K71N | Missense Mutation (SNP) | VAF 222/533 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.619); called by muse, varscan2
- INPP4B | c.1021C>G p.P341A | Missense Mutation (SNP) | VAF 140/336 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, varscan2
- LGSN | c.103G>A p.V35I | Missense Mutation (SNP) | VAF 150/352 reads (43%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.007); called by muse, varscan2
- MUC2 | c.560C>G p.S187C | Missense Mutation (SNP) | VAF 158/540 reads (29%) | SIFT deleterious (0); called by muse, varscan2
- NCOA3 | c.2150G>C p.G717A | Missense Mutation (SNP) | VAF 81/224 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.003); called by muse, varscan2
- NXT1 | c.382A>T p.I128F | Missense Mutation (SNP) | VAF 204/450 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- PALB2 | c.1987C>A p.R663S | Missense Mutation (SNP) | VAF 164/353 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.066); called by muse, varscan2
- PHF14 | c.655G>A p.V219I | Missense Mutation (SNP) | VAF 194/780 reads (25%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.006); called by muse, varscan2
- PLK5 | c.257C>T p.A86V | Missense Mutation (SNP) | VAF 150/354 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.015); called by muse, varscan2
- PPP6R3 | c.2038+1G>C p.X680_splice (on ENST00000393800 / NM_001352375.2; = p.X600_splice on NM_018312.5) | Splice Site (SNP) | VAF 76/348 reads (22%) | called by muse, varscan2
- RASGEF1A | c.136A>C p.I46L | Missense Mutation (SNP) | VAF 186/402 reads (46%) | SIFT tolerated (0.64); PolyPhen benign (0); called by muse, varscan2
- TTN | c.90408G>C p.E30136D (on ENST00000591111; = p.E22712D on NM_003319.4) | Missense Mutation (SNP) | VAF 132/408 reads (32%) | PolyPhen probably damaging (0.99); called by muse, varscan2
- WDR59 | c.89A>G p.H30R | Missense Mutation (SNP) | VAF 134/298 reads (45%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, varscan2
- ANKRD34C | c.1314G>A p.P438= | Silent (SNP) | VAF 140/337 reads (42%) | catalogued as rs780256553, COSV69854170; called by muse, varscan2
- ARAP1 | c.1758G>A p.K586= (on ENST00000393609 / NM_001040118.2; = p.K341= on NM_015242.4) | Silent (SNP) | VAF 124/425 reads (29%) | called by muse, varscan2
- ARPC2 | c.51C>T p.L17= | Silent (SNP) | VAF 205/568 reads (36%) | called by muse, varscan2
- BNC2 | c.885C>A p.P295= | Silent (SNP) | VAF 168/390 reads (43%) | catalogued as COSV66150952; called by muse, varscan2
- CUBN | c.10440T>C p.S3480= | Silent (SNP) | VAF 130/272 reads (48%) | called by muse, varscan2
- DBR1 | c.486A>G p.K162= | Silent (SNP) | VAF 94/236 reads (40%) | called by muse, varscan2
- POLR1A | c.1539C>A p.T513= | Silent (SNP) | VAF 130/498 reads (26%) | catalogued as COSV99808229; called by muse, varscan2
- RREB1 | c.363C>T p.G121= | Silent (SNP) | VAF 186/416 reads (45%) | catalogued as rs776132691; called by muse, varscan2
- SLC26A3 | c.2259T>C p.N753= | Silent (SNP) | VAF 118/445 reads (27%) | called by muse, varscan2
- SLC6A7 | c.1005C>A p.I335= | Silent (SNP) | VAF 244/810 reads (30%) | called by muse, varscan2
- SLFN12 | c.1578A>G p.R526= | Silent (SNP) | VAF 208/501 reads (42%) | called by muse, varscan2
- WDR74 | c.1137G>A p.R379= | Silent (SNP) | VAF 78/428 reads (18%) | called by muse, varscan2
- ZMIZ1 | c.1185C>T p.P395= | Silent (SNP) | VAF 142/306 reads (46%) | called by muse, varscan2
- CCIN | c.-55G>C | 5'UTR (SNP) | VAF 172/278 reads (62%) | called by muse, varscan2
- ETFDH | c.487+56C>T | Intron (SNP) | VAF 72/169 reads (43%) | called by muse, varscan2
- HDAC9 | c.*59A>G | 3'UTR (SNP) | VAF 38/144 reads (26%) | called by muse, varscan2
- LYPD1 | c.-203C>A | 5'UTR (SNP) | VAF 55/150 reads (37%) | called by muse, varscan2
- PAH | c.*29T>C | 3'UTR (SNP) | VAF 146/512 reads (29%) | called by muse, varscan2
- POMT1 | c.1764+83C>G | Intron (SNP) | VAF 16/48 reads (33%) | called by muse, varscan2
- SLC2A6 | c.1037-47C>T | Intron (SNP) | VAF 25/52 reads (48%) | called by muse, varscan2
- SYNJ2BP | c.-18C>T | 5'UTR (SNP) | VAF 87/128 reads (68%) | called by muse, varscan2
- TACO1 | c.515+39C>T | Intron (SNP) | VAF 266/436 reads (61%) | called by muse, varscan2
- ZNF175 | c.-81C>T | 5'UTR (SNP) | VAF 26/71 reads (37%) | catalogued as COSV99219389; called by muse, varscan2
